Surgical pathology report (de-identified scan), TCGA case TCGA-49-4486, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-4486-01A (Primary Tumor).

FINAL DIAGNOSIS ----- Pathologist: [REDACTED]
RIGHT LOWER LUNG (LOBECTOMY): ADENOCARCINOMA OF THE LUNG WITH
BRONCHIOLOALVEOLAR AND PAPILLARY FEATURES. PANACINAR EMPHYSEMATOUS
CHANGES. INTRAPULMONARY HEMORRHAGE. SINGLE REMOTE GRANULOMA IN HILAR
LYMPH NODE. THREE (3) PULMONARY LYMPH NODES AND BRONCHIAL AND
VASCULAR MARGINS ARE NEGATIVE FOR TUMOR. SEE NOTE.

NOTE: Special stain for fungi and acid fast bacilli are negative.

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 303ac558-0fb1-4753-a25c-1cb9c5f275e5 (TCGA-49-4486.30B3B92C-C810-4CF8-8342-F6E9D87BACFE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).